Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-8315, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-8315-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

A) PANCREAS, DUODENUM, AND PORTION OF STOMACH, PANCREATODUODENECTOMY (WHIPPLE RESECTION):

1. Invasive moderately-differentiated adenocarcinoma characterized by:
- a. Tumor size: 6 x 4.5 x 3.4 cm
- b. Tumor extent: The tumor is located in the head of the pancreas and extends to occlude the pancreatic duct, abuts the common bile duct, and shows invasion into the adjacent duodenal wall with extension up to the duodenal submucosa
- c. Additional findings: Extensive perineural invasion is identified
- d. Angiolymphatic space invasion: Absent
2. The retroperitoneal margin of resection is positive for adenocarcinoma
3. The pancreatic transection margin and the common bile duct margin are both negative for malignancy. The duodenal and gastric resection margins are negative for malignancy
4. Multiple (21) regional lymph nodes are negative for malignancy
5. The background pancreas shows fibrosing chronic pancreatitis
6. See staging parameters

B) GALLBLADDER, CHOLECYSTECTOMY:

1. Mild lymphoplasmacytic chronic cholecystitis with cholesterosis
2. Negative for malignancy

** PANCREATIC CANCER STAGING PARAMETERS ***

Case number: Patient name:

Final TNM: pT3N0M0

Stage: IIA

MACROSCOPIC

SPECIMEN TYPE

Whipple, Standard

TUMOR SITE

Pancreatic head

TUMOR SIZE

6 X 4.5 X 3.4 cm

MICROSCOPIC

HISTOLOGIC TYPE

Ductal Adenocarcinoma

HISTOLOGIC GRADE

G2: (moderately differentiated) of G4

MARGINS - PANCREATODUODENECTOMY

Involved by invasive carcinoma

Location(s): Pancreatic retroperitoneal

[page 2 of 3]
[REDACTED]

Margin(s) evaluated: Proximal (stomach), Distal (duodenum),
Bile duct, Distal pancreatic
LYMPHATIC/VASCULAR INVASION
Absent: Lymph-vascular invasion not present/Not identified
PERINEURAL INVASION
Present, Extensive

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor extends beyond the pancreas but without
involvement

of the celiac axis or the superior mesenteric artery)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 21

Total positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE SUMMARY

Final TNM: pT3N0M0

[REDACTED] stage: IIA

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

[REDACTED]

CLINICAL INFORMATION

[REDACTED]-year-old female who originally presented with jaundice and had
endoscopic ultrasound revealing a 5 cm cystic and solid mass which
obstructed the common bile duct and pancreatic duct. Fine needle aspiration
of the head of the pancreas was positive for adenocarcinoma ([REDACTED])
[REDACTED]

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Whipple

Received fresh labeled "Whipple" is a Whipple specimen that includes a 25
cm in length x 4 cm in diameter segment of duodenum, an 11 x 6 x 3 cm
portion of stomach, and an 8 x 4.5 x 4 cm portion of pancreas. The pancreas
is inked in the normal fashion. Note that there is additional orange ink
near the portal vein bed and retroperitoneum which is disrupted which is
indicated by the surgeon to be an area of disruption of the pancreatic
lesion. The common bile duct has a stent in place. The distal pancreatic
margin is taken en face and submitted on chuck 1. The common bile duct
margin is submitted on chuck 2. The disrupted area near the retroperitoneum
including the area of disruption is submitted on chuck 3.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Retroperitoneal
margin involved by adenocarcinoma, predominantly in the form of perineural
invasion. Pancreatic transection margin demonstrated fibrosing chronic
pancreatitis. The common bile duct margin is also negative" is rendered by
[REDACTED]

The common bile duct is probe patent and opened longitudinally revealing a
ragged surface that appears to be uninvolved by lesion. The pancreatic duct
is completely occluded. The pancreas is sectioned revealing a firm white
partially cystic tumor mass. The solid part is near the distal pancreas and
becomes more cystic near the retroperitoneum and area of the uncinate. No
normal pancreas is seen. The pancreas at the edge of the lesion appears
bright yellow with fat necrosis and possible pancreatitis. The lesion
including the cystic portion measures 6 x 4.5 x 3.4 cm. The mass extends to
[REDACTED]

[REDACTED]

[page 3 of 3]
[REDACTED]

the portal vein bed, within 0.1 cm of the distal pancreas margin, approaches the retroperitoneum and is also at the orange ink of the disrupted cystic area and 0.6 cm from the uncinate margin. Note that photographs are taken and tissue is taken for possible ancillary studies.

The duodenal and gastric mucosa is grossly unremarkable with no lesions. Representative sections of the pancreas lesion are submitted from proximal to distal. The pancreatic fat is searched revealing 10 tan-pink lymph nodes ranging from 0.6 to 2 cm with the largest node being the hepatic artery node. The gastric fat is searched revealing ten tan-pink 0.3 cm to 1 cm lymph nodes.

Representative sections are submitted in 26 cassettes labeled:

- 1-3. Frozen section
4. Edge of possible lesion and uncinate
5. Lesion and uncinate
- 6-9. Disrupted area with orange ink and adjacent retroperitoneum
10. Tumor and portal vein bed
11. Tumor and portal vein bed with retroperitoneal margin
12. Tumor and portal vein bed
13. Cross section of common bile duct and underlying tumor
14. Tumor and possible pancreas duct
15. Tumor and common bile duct
16. Representative tumor
17. Proximal resection margin, gastric
18. Distal resection margin, duodenum
19. Random gastric and duodenal mucosa
20. four pancreatic nodes
21. Three pancreatic nodes (one bisected and inked black)
22. One node sectioned
- 23-24. Hepatic artery node, sectioned
25. Four gastric lymph nodes
26. Six gastric lymph nodes

[REDACTED]

B) SOURCE: Gallbladder and contents

Labeled "gallbladder and contents" consists of a pink-purple, 10 x 5 x 3 cm gallbladder. The serosal surface is smooth and glistening. The cystic duct is identified with a 0.2 cm luminal diameter. The specimen is opened revealing a green-tan velvety mucosa covered by yellow flecks consistent with cholesterosis. No calculi are grossly identified. The wall is extremely edematous and ranges from 0.2-0.6 cm in thickness. Multiple representative sections of gallbladder wall and en face cystic duct margin is submitted in a single cassette.

This case is accessioned in [REDACTED]

Gross dictation by: [REDACTED]

MICROSCOPIC

A,B) The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] transcribed by [REDACTED]

[REDACTED]

[REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file ae0e27c9-30d7-4c3e-b953-9a772edf1d3f (TCGA-HZ-8315.73614CAA-E4F5-4277-BBDC-5E234EAE8D27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).